Somatic mutation profile of tumor specimen TCGA-FY-A3NP-01A (aliquot TCGA-FY-A3NP-01A-11D-A21A-08) from TCGA case TCGA-FY-A3NP, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary carcinoma, follicular variant; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage I; Age at diagnosis: 69.7 years (25,462 days).
Specimen TCGA-FY-A3NP-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 42124c46-877a-4edc-a212-f7ffedd49a0b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-FY-A3NP-10A (Blood Derived Normal), aliquot TCGA-FY-A3NP-10A-01D-A21A-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a9fa032f-6814-44e1-a45c-2b2cd3c74540

The open-access MAF lists 10 somatic variants for this specimen: 8 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 7, Silent 2, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.182A>G p.Q61R | Missense Mutation (SNP) | VAF 46/132 reads (35%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen benign (0.251); catalogued as rs11554290, COSV54736340, COSV54736624, COSV54738969, COSV54747786; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ENPEP | c.634G>A p.G212R | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as rs1200919781, COSV54452617, COSV99488003; called by muse, mutect2, varscan2
- KCNH7 | c.1324C>T p.R442* | Nonsense Mutation (SNP) | VAF 16/35 reads (46%) | catalogued as COSV59793513; called by muse, mutect2, varscan2
- LETM1 | c.200G>T p.G67V | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT tolerated (0.11); PolyPhen benign (0.058); catalogued as COSV57101934; called by muse, mutect2, varscan2
- OAS3 | c.2656G>A p.D886N | Missense Mutation (SNP) | VAF 18/40 reads (45%) | SIFT tolerated (0.13); PolyPhen benign (0.31); catalogued as COSV57446590; called by muse, mutect2, varscan2
- PLXNC1 | c.2482G>A p.V828I | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV51577067; called by muse, mutect2
- RANBP10 | c.1408A>T p.M470L | Missense Mutation (SNP) | VAF 23/72 reads (32%) | SIFT tolerated (0.71); PolyPhen benign (0.001); catalogued as COSV58158611; called by muse, mutect2, varscan2
- ZNF225 | c.1064A>G p.Y355C | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT tolerated (0.18); PolyPhen benign (0.006); catalogued as rs1329049567, COSV53471946; called by muse, mutect2, varscan2
- ADGRL1 | c.2788C>T p.L930= (on ENST00000340736 / NM_001008701.3; = p.L925= on NM_014921.5) | Silent (SNP) | VAF 3/49 reads (6%) | catalogued as COSV61565167; called by muse, mutect2
- FRG2B | c.81C>A p.I27= | Silent (SNP) | VAF 9/86 reads (10%) | catalogued as COSV71042603; called by muse, mutect2, varscan2
